TCGA case TCGA-D5-5541 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Greater Poland Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/94067eb7-98b7-4975-bab1-c09e1b454a25

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Poland; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Sigmoid colon; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 63.3 years (23,109 days); Year of diagnosis: 2010; AJCC pathologic T: T3; AJCC pathologic N: N1a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,701 days (4.7 years).
   Pathology details: Circumferential resection margin: 36; Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 8; Lymphatic invasion present: No; Non nodal tumor deposits: No; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Dexamethasone + Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 19 days; Days to treatment end: 279 days; Number of cycles: 12; Prescribed dose: 768; Prescribed dose units: mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 202 days; Disease response: Tumor Free.
- Days to follow up: 350 days; Disease response: Tumor Free.
- Days to follow up: 1,701 days (4.7 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 2.3 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 81 kg; Height: 170 cm; BMI: 28.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D5-5541-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.6; Shortest dimension: 0.3.
  Slide TCGA-D5-5541-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-D5-5541-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D5-5541-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Weight kg at diagnosis: 81 kg; Height cm at diagnosis: 170 cm; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; CEA level pretreatment: 2.3; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment: Regimen number: FOL FOX4; Pharmaceutical therapy drug name: Calcium Foliatum, fluorouracilum, oxaliplatinum, dexamethassone.
- Drug treatment, Route of administrations: Route of administration: IV.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,701 days; disease-specific survival: no event (censored), 1,701 days; disease-free interval: no event (censored), 1,701 days; progression-free interval: no event (censored), 1,701 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D5-5541-01A-01D-1649-01): tumor purity 0.78, ploidy 2.37, whole-genome doublings 0.
